Somatic mutation profile of tumor specimen C3N-02335-02 (aliquot CPT0136100009) from CPTAC case C3N-02335, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.1 years (25,246 days).
Specimen C3N-02335-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b55d55b5-8b68-4116-9f51-e38fe8976d13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02335-71 (Blood Derived Normal), aliquot CPT0136210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e0b1888-5fb0-46ca-a945-1de6d0984fac

The open-access MAF lists 120 somatic variants for this specimen: 89 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 26, Nonsense Mutation 8, Intron 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs770283083, COSV61049477; called by muse, mutect2, varscan2
- AHNAK | c.11941G>A p.D3981N | Missense Mutation (SNP) | VAF 145/590 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV57223523; called by muse, mutect2, varscan2
- ANKMY1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 43/518 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs533380242; called by muse, mutect2
- B4GALNT3 | c.2159A>G p.Q720R | Missense Mutation (SNP) | VAF 28/682 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.044); catalogued as rs1419252301; called by muse, mutect2
- CABIN1 | c.6478C>T p.P2160S | Missense Mutation (SNP) | VAF 62/1438 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54078247; called by muse, mutect2
- CASZ1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 87/711 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.799); catalogued as rs1371717413; called by muse, mutect2, varscan2
- CDH4 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 30/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778645751, COSV100849076; called by muse, mutect2
- CDHR1 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140077265, COSV100258800; ClinVar: uncertain significance; called by muse, mutect2
- CSPP1 | c.2102A>G p.H701R (on ENST00000676605; = p.H660R on NM_024790.6) | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1563682537; called by muse, mutect2
- DIP2A | c.4336G>T p.G1446* | Nonsense Mutation (SNP) | VAF 28/238 reads (12%) | catalogued as COSV59488443; called by mutect2, varscan2
- FAM135B | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52749802, COSV99418979, COSV99424084; called by muse, mutect2, varscan2
- FAT4 | c.2606G>A p.S869N | Missense Mutation (SNP) | VAF 67/526 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as rs1560754651; called by muse, mutect2, varscan2
- GCOM1 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs759187975; called by muse, mutect2, varscan2
- GPR161 | c.887G>T p.W296L | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54795064; called by muse, mutect2, varscan2
- GRM1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 18/401 reads (4%) | catalogued as COSV51108019; called by muse, mutect2
- HS3ST3A1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs574000502; called by muse, mutect2
- IL17RA | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 72/874 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100083558; called by muse, mutect2
- KHSRP | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.639); catalogued as rs762120100; called by muse, mutect2, varscan2
- KIAA1671 | c.4994G>A p.R1665H | Missense Mutation (SNP) | VAF 120/2046 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs371966904; called by muse, mutect2
- KRTAP10-9 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 113/800 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782533154; called by muse, mutect2, varscan2
- LEFTY1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1036567526; called by muse, mutect2
- MAPK15 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 92/914 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV62027967; called by muse, mutect2, varscan2
- MEFV | c.2133A>G p.I711M | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs1355954520; called by muse, mutect2
- MRC2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 138/569 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.012); catalogued as rs1193590556; called by muse, mutect2, varscan2
- MRPL9 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1017853663; called by muse, mutect2
- NLRP8 | c.1338C>G p.I446M | Missense Mutation (SNP) | VAF 71/444 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV52593681; called by muse, mutect2, varscan2
- PCDH17 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 86/517 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100931494, COSV64973047; called by muse, mutect2, varscan2
- PCDHA5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1554129666, COSV65350345; called by muse, mutect2
- PXDNL | c.3100C>T p.R1034* | Nonsense Mutation (SNP) | VAF 62/720 reads (9%) | catalogued as rs1221098951, COSV62497038; called by muse, mutect2
- ROS1 | c.6805C>T p.R2269* | Nonsense Mutation (SNP) | VAF 60/440 reads (14%) | catalogued as rs202153378, COSV100877678, COSV63851197; called by muse, mutect2, varscan2
- SALL3 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 70/808 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs751561264; called by muse, mutect2
- SCN10A | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 49/404 reads (12%) | catalogued as rs763084100, COSV71860285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 40/1456 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as rs554208670, COSV100635982; ClinVar: uncertain significance; called by muse, mutect2
- TSHZ2 | c.578G>C p.S193T | Missense Mutation (SNP) | VAF 71/587 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61586770; called by muse, mutect2, varscan2
- XKR6 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 69/501 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs772365739; called by muse, mutect2, varscan2
- ZBED9 | c.2138G>C p.R713T | Missense Mutation (SNP) | VAF 20/593 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV71729768; called by muse, mutect2
- ZNF716 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1554324553, COSV101348702, COSV70780316; called by muse, mutect2, varscan2
- ADGRG4 | c.6734T>C p.F2245S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRV1 | c.10382C>A p.S3461* | Nonsense Mutation (SNP) | VAF 44/362 reads (12%) | called by muse, mutect2, varscan2
- AHNAK | c.12820G>C p.D4274H | Missense Mutation (SNP) | VAF 152/658 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ANO2 | c.999G>A p.W333* (on ENST00000356134 / NM_001278597.3; = p.W337* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 47/427 reads (11%) | called by muse, mutect2, varscan2
- ASB12 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ATG16L2 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 97/1357 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ATR | c.6768T>G p.S2256R | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- C17orf64 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 15/464 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CDCA4 | c.512C>G p.T171S | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CFAP54 | c.2543C>A p.A848E | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CHFR | c.895G>C p.E299Q (on ENST00000432561 / NM_001161345.1; = p.E258Q on NM_018223.2) | Missense Mutation (SNP) | VAF 41/655 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2
- DOLK | c.1514G>C p.W505S | Missense Mutation (SNP) | VAF 17/361 reads (5%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.961); called by muse, mutect2
- DPPA2 | c.607A>T p.N203Y | Missense Mutation (SNP) | VAF 54/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EFNB1 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ENC1 | c.1414T>G p.W472G | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EXOC1 | c.2192A>G p.E731G | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM229B | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FAT3 | c.3992C>T p.A1331V | Missense Mutation (SNP) | VAF 26/874 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNF4G | c.813G>T p.E271D (on ENST00000354370 / NM_001330561.2; = p.E318D on NM_004133.5) | Missense Mutation (SNP) | VAF 61/635 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2
- HSPA4 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISLR2 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- KIAA0895 | c.949G>C p.V317L (on ENST00000297063 / NM_001100425.2; = p.V266L on NM_015314.3) | Missense Mutation (SNP) | VAF 39/473 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.043); called by muse, mutect2
- LRP6 | c.1643C>G p.T548S | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MAPK15 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 92/800 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, varscan2
- MSR1 | c.956T>A p.L319H | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MYCBP2 | c.7183G>A p.E2395K (on ENST00000357337; = p.E2433K on NM_015057.5) | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NDUFAF7 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 21/255 reads (8%) | called by muse, mutect2
- NKRF | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.096); called by muse, mutect2
- OR1D2 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 56/500 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by mutect2, varscan2
- P2RY2 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 222/1389 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by mutect2, varscan2
- PLEK | c.120T>G p.S40R | Missense Mutation (SNP) | VAF 42/407 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PLEKHO1 | c.124_128delinsCCCCC p.K42_N43delinsPP | Missense Mutation (ONP) | VAF 44/426 reads (10%) | called by mutect2*, pindel
- PRAME | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 129/612 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PRSS58 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 28/581 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- R3HDML | c.475T>A p.W159R | Missense Mutation (SNP) | VAF 120/444 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RPS13 | c.446T>A p.L149Q | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RTL1 | c.834T>G p.F278L | Missense Mutation (SNP) | VAF 35/630 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- SLC39A4 | c.1637C>T p.A546V (on ENST00000301305 / NM_001374839.1; = p.A521V on NM_017767.3) | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC39A4 | c.1441C>G p.L481V (on ENST00000301305 / NM_001374839.1; = p.L456V on NM_017767.3) | Missense Mutation (SNP) | VAF 55/751 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.043); called by muse, mutect2
- SUPV3L1 | c.893A>T p.D298V | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF6L | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 56/485 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- TMEM132D | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNFSF8 | c.552A>T p.K184N | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TRAV36DV7 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC39B | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.15); called by muse, mutect2
- TTN | c.4717C>T p.L1573F (on ENST00000591111; = p.L1527F on NM_003319.4) | Missense Mutation (SNP) | VAF 34/472 reads (7%) | PolyPhen possibly damaging (0.857); called by muse, mutect2
- VIL1 | c.2362A>T p.R788W | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- VWA3B | c.787T>C p.C263R | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZBED9 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 46/726 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ZC3HC1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 30/379 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ZNF334 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZRANB3 | c.2366T>C p.V789A | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- BTBD11 | c.2259G>A p.Q753= (on ENST00000280758 / NM_001018072.2; = p.Q290= on NM_001017523.2) | Silent (SNP) | VAF 35/347 reads (10%) | called by muse, mutect2, varscan2
- CDC34 | c.132C>T p.A44= | Silent (SNP) | VAF 40/334 reads (12%) | called by muse, varscan2
- DOCK3 | c.2733C>A p.L911= | Silent (SNP) | VAF 53/364 reads (15%) | called by muse, mutect2, varscan2
- GLS2 | c.594G>A p.L198= | Silent (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2, varscan2
- GPR12 | c.534C>T p.G178= | Silent (SNP) | VAF 60/575 reads (10%) | called by muse, mutect2, varscan2
- ILF3 | c.1341G>A p.G447= | Silent (SNP) | VAF 12/431 reads (3%) | catalogued as COSV51553668; called by muse, mutect2
- IQCM | c.246C>T p.A82= | Silent (SNP) | VAF 69/521 reads (13%) | catalogued as rs17026378; called by muse, mutect2, varscan2
- LRRC7 | c.1980G>A p.K660= (on ENST00000651989 / NM_001370785.2; = p.K627= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/271 reads (14%) | catalogued as rs865959817, COSV50504532; called by muse, mutect2, varscan2
- MED17 | c.270T>C p.P90= | Silent (SNP) | VAF 37/974 reads (4%) | called by muse, mutect2
- MRE11 | c.297C>G p.V99= | Silent (SNP) | VAF 76/822 reads (9%) | called by muse, mutect2
- MUC5B | c.7278C>A p.P2426= | Silent (SNP) | VAF 67/634 reads (11%) | called by muse, mutect2, varscan2
- NLGN2 | c.762C>T p.G254= | Silent (SNP) | VAF 66/507 reads (13%) | catalogued as rs1446246633, COSV57211174; called by muse, mutect2, varscan2
- NRIP1 | c.2367G>A p.Q789= | Silent (SNP) | VAF 47/424 reads (11%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1836C>T p.P612= | Silent (SNP) | VAF 106/483 reads (22%) | catalogued as rs1488646083, COSV99549312; called by muse, mutect2, varscan2
- PTPRD | c.708A>T p.P236= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- RBFOX2 | c.936G>A p.G312= (on ENST00000438146 / NM_001349995.2; = p.G242= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/1318 reads (5%) | called by muse, mutect2
- RBPJL | c.1215C>T p.H405= | Silent (SNP) | VAF 122/531 reads (23%) | called by muse, mutect2, varscan2
- S100A11 | c.49C>T p.L17= | Silent (SNP) | VAF 38/330 reads (12%) | called by muse, mutect2, varscan2
- SHANK2 | c.3936C>G p.G1312= | Silent (SNP) | VAF 50/1656 reads (3%) | called by muse, mutect2
- SLCO2B1 | c.1371C>T p.S457= | Silent (SNP) | VAF 70/2248 reads (3%) | called by muse, mutect2
- SLCO4A1 | c.210G>A p.R70= | Silent (SNP) | VAF 122/768 reads (16%) | called by muse, mutect2, varscan2
- SMTNL1 | c.849C>T p.S283= (on ENST00000399154; = p.S320= on NM_001105565.2) | Silent (SNP) | VAF 36/493 reads (7%) | called by muse, mutect2
- TFAP2C | c.888C>T p.A296= | Silent (SNP) | VAF 38/428 reads (9%) | catalogued as rs748900491, COSV52372675; called by muse, mutect2
- TGM1 | c.1614G>A p.E538= | Silent (SNP) | VAF 42/394 reads (11%) | called by muse, mutect2, varscan2
- TMEM134 | c.96C>T p.R32= | Silent (SNP) | VAF 70/1658 reads (4%) | called by muse, mutect2
- TYMP | c.1326G>C p.R442= | Silent (SNP) | VAF 22/414 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+449C>A | Intron (SNP) | VAF 118/248 reads (48%) | called by muse, varscan2
- ARMCX4 | c.1038+450T>C | Intron (SNP) | VAF 125/261 reads (48%) | catalogued as rs1556008085; called by muse, mutect2, varscan2
- C2CD6 | c.1582-3571C>T | Intron (SNP) | VAF 44/303 reads (15%) | catalogued as rs1468643479; called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1048G>T | Intron (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- ZNF431 | c.320-7153T>G | Intron (SNP) | VAF 45/294 reads (15%) | called by muse, mutect2, varscan2
